Somatic mutation profile of tumor specimen ALCH-B3JP-TTP1-A (aliquot ALCH-B3JP-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3JP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.0 years (23,729 days).
Specimen ALCH-B3JP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32068a0a-f6a2-4fc1-b16e-98d1665d2ce9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3JP-NB1-A (Blood Derived Normal), aliquot ALCH-B3JP-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f45a88d-733d-4aa7-b4d5-6b13face2b9f

The open-access MAF lists 428 somatic variants for this specimen: 299 protein-altering or splice-affecting, 80 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 80, Intron 20, Nonsense Mutation 17, RNA 15, Frame Shift Del 11, Splice Region 7, 5'UTR 6, 3'UTR 5, Frame Shift Ins 4, Splice Site 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 93/176 reads (53%) | catalogued as rs1481151440, COSV65953073; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F13A1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 101/325 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913072, CM960521, COSV53561772; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4300C>T p.R1434C | Missense Mutation (SNP) | VAF 107/324 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs730880800, CM115853, COSV62517542; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 43/89 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4089C>A p.H1363Q | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs1211875269, CM107089, COSV56849888, COSV56854869; called by muse, mutect2, varscan2
- ADAMTS12 | c.3448G>T p.G1150C | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as COSV61261578, COSV61263408; called by muse, mutect2, varscan2
- ADAMTS12 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs147018630; called by muse, mutect2, varscan2
- AKAP6 | c.4775G>A p.R1592Q | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776536609, COSV99797485; called by muse, mutect2, varscan2
- AKAP9 | c.9838A>G p.N3280D (on ENST00000359028; = p.N3256D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs755045020; called by muse, mutect2, varscan2
- ARID3A | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as rs561845616; called by muse, mutect2, varscan2
- BBS10 | c.700A>G p.R234G | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs534432274; called by muse, mutect2, varscan2
- CCDC88C | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs370667337; called by muse, mutect2
- CDAN1 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 126/409 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62331396; called by muse, mutect2, varscan2
- CDH2 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV52271407; called by muse, mutect2, varscan2
- CDHR5 | c.1625C>G p.S542C (on ENST00000358353 / NM_001171968.2; = p.S548C on NM_021924.5) | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs141060537; called by muse, mutect2, varscan2
- COL1A2 | c.3346T>A p.F1116I | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.205); catalogued as COSV51963368; called by muse, mutect2, varscan2
- COL22A1 | c.502G>C p.A168P | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57327661; called by muse, mutect2
- CORIN | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56686154; called by muse, mutect2, varscan2
- CORO1C | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760283072; called by muse, mutect2, varscan2
- CSGALNACT2 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756983842; called by muse, mutect2, varscan2
- CTNNA3 | c.2016G>T p.K672N | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65525686; called by muse, mutect2, varscan2
- DCC | c.3518C>G p.P1173R | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV71428023; called by muse, mutect2, varscan2
- DPY19L3 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as COSV60475702; called by muse, mutect2, varscan2
- DTL | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1186220211; called by muse, mutect2, varscan2
- ESR1 | c.1323G>C p.Q441H | Missense Mutation (SNP) | VAF 159/537 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1341571386; called by muse, mutect2, varscan2
- EXOC3 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV59268602; called by muse, mutect2, varscan2
- FAM161A | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1354691410; called by muse, mutect2, varscan2
- FBXL16 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV50204854; called by muse, mutect2, varscan2
- FEZF2 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 129/295 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99334899; called by muse, mutect2, varscan2
- FLI1 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61380749; called by muse, mutect2, varscan2
- FLNC | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990718751; called by muse, mutect2, varscan2
- FMNL1 | c.485+10dup | Splice Region (INS) | VAF 48/167 reads (29%) | catalogued as rs757071665; called by mutect2, pindel, varscan2
- GLYATL2 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV99780446; called by muse, mutect2
- GPR22 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51752647; called by muse, mutect2, varscan2
- HSPA1L | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100989313; called by muse, mutect2, varscan2
- KCNH4 | c.767C>A p.T256N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as rs201395423; called by muse, mutect2, varscan2
- KCNQ3 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 116/460 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as COSV66469244; called by muse, mutect2, varscan2
- KMT2D | c.6991del p.L2331* | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | catalogued as CD1312976; called by mutect2, pindel, varscan2
- KRT1 | c.1864G>T p.G622C | Missense Mutation (SNP) | VAF 111/457 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV52868452; called by muse, mutect2, varscan2
- KSR1 | c.2059A>C p.K687Q (on ENST00000644974 / NM_001367810.1; = p.K572Q on NM_014238.2) | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52041149; called by muse, mutect2, varscan2
- LRP1B | c.10599G>T p.W3533C | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV101255203; called by muse, mutect2, varscan2
- MAP3K19 | c.3556G>A p.D1186N | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768975491; called by muse, mutect2, varscan2
- MARCHF8 | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV100166038; called by muse, mutect2, varscan2
- MS4A8 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs776863093, COSV55753006; called by muse, mutect2, varscan2
- NLGN1 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 77/564 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.693); catalogued as COSV64344878; called by muse, mutect2, varscan2
- NTRK3 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 140/433 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV58133510; called by muse, mutect2, varscan2
- NXF3 | c.1161-5T>C | Splice Region (SNP) | VAF 70/101 reads (69%) | catalogued as rs1339815142; called by muse, mutect2, varscan2
- OPA1 | c.1498C>T p.R500C (on ENST00000361510 / NM_130837.3; = p.R445C on NM_015560.3) | Missense Mutation (SNP) | VAF 51/1204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs886043340, COSV62479746; called by muse, mutect2
- OR2M7 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV58738534; called by muse, mutect2, varscan2
- OR5R1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.58); catalogued as COSV100393614; called by muse, varscan2
- OR8G1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs760406916; called by muse, mutect2, varscan2
- OR8J1 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57318154, COSV57319804, COSV57319848; called by muse, mutect2
- PAPPA | c.2584C>A p.L862M | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.327); catalogued as rs1182880914; called by muse, mutect2, varscan2
- PAPPA2 | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV62781266; called by muse, mutect2, varscan2
- PCDH10 | c.2317C>A p.R773S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.987); catalogued as rs1458636323, COSV52104626; called by muse, mutect2, varscan2
- PCDH8 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.136); catalogued as rs758769450, COSV100131717; called by muse, varscan2
- PDE10A | c.1555del p.Y519Ifs*15 | Frame Shift Del (DEL) | VAF 52/261 reads (20%) | catalogued as COSV63102040; called by pindel, varscan2
- PKHD1L1 | c.9880G>A p.G3294R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs372993231; called by muse, varscan2
- PON1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 61/513 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs371338407; called by muse, mutect2, varscan2
- PRDM1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as rs765744926, COSV100958940; called by muse, mutect2, varscan2
- PTPN22 | c.2282-1G>T p.X761_splice (on ENST00000359785 / NM_001193431.2; = p.X706_splice on NM_012411.5) | Splice Site (SNP) | VAF 36/72 reads (50%) | catalogued as COSV100703357, COSV63086587; called by muse, mutect2, varscan2
- RBMXL3 | c.2752G>A p.G918S | Missense Mutation (SNP) | VAF 90/126 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs1330513381; called by muse, mutect2, varscan2
- RIC3 | c.628G>C p.E210Q (on ENST00000309737 / NM_001206671.4; = p.E209Q on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58305319; called by muse, mutect2, varscan2
- RNF115 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.066); catalogued as rs1553718532; called by muse, mutect2, varscan2
- SH2D2A | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs780926029; called by muse, mutect2, varscan2
- SIN3A | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as rs751240570; called by muse, mutect2, varscan2
- SIPA1L1 | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV62169316, COSV62171138; called by muse, mutect2, varscan2
- SLAMF8 | c.160T>C p.W54R | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.832); catalogued as rs755353273; called by muse, mutect2, varscan2
- SLC25A41 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV58599619; called by muse, mutect2
- SORCS3 | c.3563C>A p.P1188H | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV63806908; called by muse, mutect2, varscan2
- SYT17 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 116/419 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100810634; called by muse, mutect2, varscan2
- TLR4 | c.566G>T p.S189I (on ENST00000355622 / NM_138554.5; = p.S149I on NM_003266.4) | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV62923276; called by muse, mutect2, varscan2
- TMEM70 | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100383988; called by muse, mutect2, varscan2
- TMEM87B | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs62001036; called by muse, mutect2, varscan2
- TRIM7 | c.619-7G>C | Splice Region (SNP) | VAF 67/152 reads (44%) | catalogued as COSV99220474; called by muse, mutect2, varscan2
- TUBG2 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52219791; called by muse, mutect2, varscan2
- UHRF1 | c.1264C>A p.P422T (on ENST00000612630 / NM_001290050.1; = p.P435T on NM_013282.4) | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53575127; called by muse, mutect2, varscan2
- USP17L7 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 190/761 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751806728; called by muse, mutect2, varscan2
- USP35 | c.3040C>T p.H1014Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs1231963300; called by muse, mutect2, varscan2
- VIM | c.1230-8G>T | Splice Region (SNP) | VAF 118/436 reads (27%) | catalogued as rs752183652; called by muse, mutect2, varscan2
- VWA5B1 | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 103/208 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV57055597, COSV99232912; called by muse, mutect2, varscan2
- WSCD1 | c.1710G>T p.R570S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58494737; called by muse, mutect2, varscan2
- ZBTB10 | c.2572C>T p.R858* (on ENST00000430430; = p.R834* on NM_023929.4) | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as rs765699429, COSV100990055, COSV100990176; called by muse, mutect2, varscan2
- ZNF737 | c.1560C>A p.C520* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | catalogued as COSV101417681; called by muse, mutect2, varscan2
- ZRANB3 | c.2875G>T p.E959* | Nonsense Mutation (SNP) | VAF 38/161 reads (24%) | catalogued as COSV99923271; called by muse, mutect2, varscan2
- ABCA12 | c.3254T>C p.V1085A (on ENST00000272895 / NM_173076.3; = p.V767A on NM_015657.3) | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- ABCA13 | c.5274G>C p.Q1758H | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ABCA13 | c.14760G>C p.E4920D | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ABCA6 | c.4378A>G p.K1460E | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ABCA8 | c.4738G>T p.E1580* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- AC005833.1 | c.1088C>A p.A363D | Missense Mutation (SNP) | VAF 41/393 reads (10%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- ACCSL | c.586T>C p.C196R | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSF2 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ADGRF5 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 70/166 reads (42%) | called by muse, mutect2, varscan2
- ADGRL4 | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AKAP5 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKRD36 | c.3944A>T p.Q1315L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by mutect2, varscan2
- ANKRD36C | c.4731A>G p.I1577M | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ANXA5 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 105/203 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APTX | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, varscan2
- AQP12B | c.322C>A p.L108M (on ENST00000621682; = p.L120M on NM_001102467.2) | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- AR | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 94/177 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASNS | c.943T>C p.F315L | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ATP10A | c.979+1G>C p.X327_splice | Splice Site (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- AUTS2 | c.1793G>A p.G598D | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA2D1 | c.3027G>C p.M1009I (on ENST00000356253 / NM_001366867.1; = p.M997I on NM_000722.4) | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2
- CASC3 | c.1641C>A p.Y547* | Nonsense Mutation (SNP) | VAF 78/224 reads (35%) | called by muse, mutect2, varscan2
- CCDC141 | c.4019G>C p.G1340A | Missense Mutation (SNP) | VAF 124/555 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CCDC141 | c.3683C>T p.A1228V | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC194 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CDH12 | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK4 | c.150dup p.I51Hfs*6 | Frame Shift Ins (INS) | VAF 109/522 reads (21%) | called by mutect2, pindel, varscan2
- CDRT15P3 | n.537T>A | Splice Region (SNP) | VAF 90/264 reads (34%) | called by muse, mutect2, varscan2
- CDYL2 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP85L | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CILP2 | c.868+2T>G p.X290_splice | Splice Site (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- CMTM2 | c.342G>C p.L114F | Missense Mutation (SNP) | VAF 82/338 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CNOT1 | c.7069G>T p.A2357S | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNOT1 | c.3416T>G p.V1139G | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CNTN3 | c.1702C>G p.Q568E | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- COL13A1 | c.1329G>A p.M443I (on ENST00000398978 / NM_001130103.2; = p.M386I on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL15A1 | c.1981G>T p.G661C | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL19A1 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.889A>T p.T297S | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- COL6A5 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- COPA | c.2641G>A p.D881N | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, varscan2
- COX7B2 | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CPNE9 | c.297+1del | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- CYP2S1 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DEPDC4 | c.574T>G p.S192A | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DGKA | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DIXDC1 | c.1637G>T p.S546I (on ENST00000440460 / NM_001037954.4; = p.S335I on NM_033425.4) | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMXL2 | c.4232C>A p.T1411N | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- DNAI2 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOP1A | c.6720G>T p.W2240C | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOP1A | c.6721C>T p.P2241S | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- DSEL | c.2546G>T p.S849I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DSG2 | c.2313C>A p.F771L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EIPR1 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 55/212 reads (26%) | called by muse, mutect2, varscan2
- EIPR1 | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EQTN | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERV3-1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERVMER34-1 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 89/178 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ESRP2 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ETV1 | c.1419A>T p.E473D | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAM135B | c.3692C>A p.P1231H | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM135B | c.3431G>T p.C1144F | Missense Mutation (SNP) | VAF 119/367 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCD2 | c.3898C>G p.L1300V | Missense Mutation (SNP) | VAF 152/359 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- FCGBP | c.6989C>A p.P2330Q | Missense Mutation (SNP) | VAF 579/1571 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- FCRL2 | c.1234A>T p.T412S | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FGF7 | c.441T>A p.H147Q | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FMNL3 | c.1219del p.H407Ifs*9 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel
- FNDC1 | c.5640T>A p.Y1880* | Nonsense Mutation (SNP) | VAF 95/350 reads (27%) | called by muse, mutect2, varscan2
- FNDC7 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); called by muse, mutect2
- FOXL1 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSD2 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- FSIP2 | c.9890G>A p.G3297D | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GCM2 | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 69/400 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GEMIN8 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 79/137 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- GFPT2 | c.279G>T p.W93C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGCX | c.878T>G p.L293R | Missense Mutation (SNP) | VAF 123/363 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLE1 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLYR1 | c.217del p.I73Lfs*11 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- GMNC | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 67/676 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- GNPAT | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 123/401 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC1 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- GRID1 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- HELT | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HMCN1 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 96/364 reads (26%) | called by muse, mutect2, varscan2
- HPS5 | c.2188G>A p.A730T (on ENST00000349215 / NM_181507.2; = p.A616T on NM_007216.4) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HR | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HTRA1 | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 172/387 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ICE1 | c.3238G>T p.G1080* | Nonsense Mutation (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2, varscan2
- IGF1 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGKV1D-17 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 140/472 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.312); called by muse, varscan2
- IRAK1 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 72/104 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KCNA5 | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH5 | c.2113C>G p.P705A | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- KIAA1755 | c.1551T>A p.A517= | Splice Region (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- LAMA2 | c.3411G>T p.K1137N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LAMA2 | c.4981G>T p.G1661C | Missense Mutation (SNP) | VAF 124/426 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- LBP | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 137/396 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- LMAN2L | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- LMLN | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 250/365 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- LMLN | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 45/680 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.27); called by muse, mutect2
- LPA | c.4556del p.T1519Kfs*11 | Frame Shift Del (DEL) | VAF 68/298 reads (23%) | called by mutect2, pindel, varscan2
- LRFN5 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1 | c.12302A>G p.Y4101C | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRP1B | c.9397A>G p.R3133G | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1B | c.8515C>A p.Q2839K | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC37B | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 134/484 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4B | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 122/181 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP4 | c.1948G>T p.G650C (on ENST00000308370 / NM_001042544.1; = p.G613C on NM_003573.2) | Missense Mutation (SNP) | VAF 114/175 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LZTS3 | c.1939A>G p.S647G (on ENST00000329152; = p.S601G on NM_001282533.2) | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAEL | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MBLAC1 | c.643C>G p.R215G | Missense Mutation (SNP) | VAF 190/428 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- MEF2D | c.1101_1109del p.Q375_Q377del | In Frame Del (DEL) | VAF 25/217 reads (12%) | called by mutect2, pindel, varscan2
- MEPE | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIER3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MINAR1 | c.2519G>A p.G840D | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MKKS | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MRPS30 | c.1005G>T p.W335C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A4E | c.852C>A p.S284R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- MUC12 | c.2614C>A p.P872T (on ENST00000379442; = p.P729T on NM_001164462.1) | Missense Mutation (SNP) | VAF 112/2530 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MUC16 | c.25447A>G p.T8483A | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MYH1 | c.4732A>T p.R1578W | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYH14 | c.3892A>T p.K1298* | Nonsense Mutation (SNP) | VAF 40/60 reads (67%) | called by mutect2, varscan2
- NAA35 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NBPF14 | c.1916G>T p.C639F | Missense Mutation (SNP) | VAF 23/1090 reads (2%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); called by muse, mutect2
- NES | c.2490G>C p.K830N | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- NOX3 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NUB1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- OR10H1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by mutect2, varscan2
- OR13C2 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR2M5 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- OR2T33 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- OR4C6 | c.470A>T p.Q157L | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR4N2 | c.694G>C p.A232P | Missense Mutation (SNP) | VAF 104/664 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- OR5AP2 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- OR8I2 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSMR | c.430_432del p.T144del | In Frame Del (DEL) | VAF 23/266 reads (9%) | called by mutect2, pindel
- OSMR | c.2173A>G p.S725G | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PANX3 | c.770dup p.N257Kfs*17 | Frame Shift Ins (INS) | VAF 47/152 reads (31%) | called by mutect2, pindel, varscan2
- PCDH11X | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 121/194 reads (62%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PCDHA13 | c.15G>C p.W5C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, varscan2
- PID1 | c.331A>T p.T111S (on ENST00000354069 / NM_001330156.1; = p.T109S on NM_017933.5) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PIEZO2 | c.6365G>C p.S2122T | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLCB1 | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PLCB1 | c.1738A>T p.T580S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.237); called by muse, varscan2
- PNMA1 | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- POLQ | c.4223A>G p.D1408G | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLRMT | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, varscan2
- PPP1R9B | c.1109G>T p.R370L | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PRDM9 | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PROM2 | c.2120A>T p.N707I | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PRR27 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRSS55 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTCH1 | c.3910A>T p.R1304W | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PYGL | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 93/324 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- R3HDML | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RB1CC1 | c.3748A>G p.K1250E | Missense Mutation (SNP) | VAF 143/290 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM19 | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RCE1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RGPD8 | c.1269C>A p.Y423* | Nonsense Mutation (SNP) | VAF 38/273 reads (14%) | called by muse, mutect2, varscan2
- RGS17 | c.538A>T p.T180S | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RMND5A | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- RORB | c.534G>T p.Q178H (on ENST00000396204 / NM_001365023.1; = p.Q167H on NM_006914.4) | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ROS1 | c.1840G>T p.V614L | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RUBCNL | c.1938G>T p.R646S | Missense Mutation (SNP) | VAF 93/157 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SCN7A | c.2604A>T p.Q868H | Missense Mutation (SNP) | VAF 100/261 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SEC61A1 | c.1202T>C p.M401T | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, varscan2
- SETX | c.405A>T p.E135D | Missense Mutation (SNP) | VAF 123/458 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC4A4 | c.1915A>T p.I639L (on ENST00000264485 / NM_001098484.3; = p.I595L on NM_003759.4) | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A5 | c.1673del p.P558Lfs*12 | Frame Shift Del (DEL) | VAF 158/581 reads (27%) | called by mutect2, pindel, varscan2
- SLCO1B3 | c.1869G>T p.R623S | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SMARCD2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SNRNP27 | c.413+4T>C | Splice Region (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- SOGA1 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 142/340 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SPATA31E1 | c.3875C>A p.P1292H | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPTBN5 | c.5672A>T p.Q1891L | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SVIP | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYNE1 | c.20017G>C p.V6673L (on ENST00000367255 / NM_182961.4; = p.V6602L on NM_033071.3) | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SYNE1 | c.1247C>A p.A416D (on ENST00000367255 / NM_182961.4; = p.A423D on NM_033071.3) | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TCTN3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 68/166 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- THSD7B | c.3406G>C p.G1136R (on ENST00000272643; = p.G1134R on NM_001316349.2) | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TMEM132C | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.56); called by muse, mutect2, varscan2
- TMEM214 | c.772A>T p.I258F | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TNK2 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPH2 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV18 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM36 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 94/167 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM64B | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 55/441 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.16879G>T p.G5627W (on ENST00000591111; = p.G4700W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/181 reads (24%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TULP1 | c.966_967insA p.S323Ifs*61 | Frame Shift Ins (INS) | VAF 117/346 reads (34%) | called by mutect2, pindel, varscan2
- TXNRD1 | c.1363del p.V455* (on ENST00000525566 / NM_001093771.3; = p.V357* on NM_003330.4) | Frame Shift Del (DEL) | VAF 39/141 reads (28%) | called by mutect2, pindel, varscan2
- UBA6 | c.2822_2825del p.V941Gfs*31 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- UBD | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- UBE2L6 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- UBR1 | c.4399A>T p.S1467C | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBTFL1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 150/315 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VPREB1 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 108/166 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- VPS13B | c.5227G>A p.V1743I | Missense Mutation (SNP) | VAF 131/470 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WASHC2C | c.3598_3599del p.P1200Sfs*5 (on ENST00000336378; = p.P1179Sfs*5 on NM_015262.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 147/479 reads (31%) | called by mutect2, pindel, varscan2
- WDR53 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 25/529 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- WDR90 | c.3388A>C p.T1130P | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- WFDC1 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZBBX | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 252/371 reads (68%) | SIFT tolerated (0.58); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZBTB22 | c.1403dup p.S469* | Frame Shift Ins (INS) | VAF 23/108 reads (21%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.6811G>C p.V2271L | Missense Mutation (SNP) | VAF 75/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZFHX4 | c.8071G>T p.E2691* | Nonsense Mutation (SNP) | VAF 124/342 reads (36%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10558T>A p.C3520S | Missense Mutation (SNP) | VAF 122/339 reads (36%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZG16 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ZNF234 | c.1550G>A p.C517Y | Missense Mutation (SNP) | VAF 134/204 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF430 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 70/270 reads (26%) | called by muse, mutect2, varscan2
- ZNF506 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ZNF652 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 60/155 reads (39%) | called by muse, mutect2, varscan2
- ZNF668 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF776 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 61/154 reads (40%) | called by muse, mutect2, varscan2
- ZP1 | c.1376del p.G459Afs*32 | Frame Shift Del (DEL) | VAF 35/138 reads (25%) | called by mutect2, pindel, varscan2
- AC011455.2 | c.654G>A p.E218= | Silent (SNP) | VAF 25/434 reads (6%) | catalogued as rs764014661; called by muse, mutect2
- ACVR1C | c.1392T>C p.C464= | Silent (SNP) | VAF 41/140 reads (29%) | called by muse, varscan2
- ADGRD1 | c.1206C>T p.A402= | Silent (SNP) | VAF 117/362 reads (32%) | catalogued as COSV55443762; called by muse, mutect2, varscan2
- AKR1B15 | c.273C>A p.I91= | Silent (SNP) | VAF 83/294 reads (28%) | called by muse, mutect2, varscan2
- AL121899.2 | c.2041C>T p.L681= | Silent (SNP) | VAF 56/190 reads (29%) | called by muse, mutect2, varscan2
- ANKS1B | c.1077T>C p.N359= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- C3orf80 | c.486C>G p.G162= | Silent (SNP) | VAF 90/276 reads (33%) | called by muse, mutect2, varscan2
- C4orf54 | c.2106C>A p.A702= | Silent (SNP) | VAF 61/302 reads (20%) | called by muse, mutect2, varscan2
- C7 | c.2460G>A p.A820= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as rs369115220, COSV100496691; called by muse, varscan2
- CACNA1S | c.2931C>T p.D977= | Silent (SNP) | VAF 90/373 reads (24%) | catalogued as rs374912997; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC158 | c.1731G>A p.L577= | Silent (SNP) | VAF 92/367 reads (25%) | called by muse, mutect2, varscan2
- CD1A | c.983A>G p.*328= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1457852939; called by muse, mutect2, varscan2
- CES2 | c.912C>T p.N304= | Silent (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- CHRNB2 | c.858C>T p.I286= | Silent (SNP) | VAF 70/175 reads (40%) | catalogued as rs865998992, COSV63808978; called by muse, mutect2, varscan2
- CLK2 | c.361C>A p.R121= | Silent (SNP) | VAF 79/270 reads (29%) | catalogued as COSV62878063; called by muse, mutect2, varscan2
- CNR1 | c.612G>T p.V204= | Silent (SNP) | VAF 27/213 reads (13%) | catalogued as COSV62992813; called by muse, mutect2, varscan2
- COBL | c.2511C>T p.P837= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as rs373421935; called by muse, mutect2, varscan2
- COL11A2 | c.5034T>A p.T1678= (on ENST00000341947 / NM_080680.3; = p.T1571= on NM_080679.2) | Silent (SNP) | VAF 48/126 reads (38%) | called by muse, mutect2, varscan2
- COL5A2 | c.1422T>A p.G474= | Silent (SNP) | VAF 125/266 reads (47%) | called by muse, mutect2, varscan2
- CPA5 | c.1053G>A p.K351= | Silent (SNP) | VAF 60/317 reads (19%) | catalogued as COSV62570686; called by muse, mutect2, varscan2
- CPA6 | c.1083A>T p.V361= | Silent (SNP) | VAF 74/361 reads (20%) | called by muse, mutect2, varscan2
- CRACD | c.2367C>T p.C789= | Silent (SNP) | VAF 90/475 reads (19%) | called by muse, mutect2, varscan2
- CROCC | c.1044G>A p.L348= | Silent (SNP) | VAF 76/279 reads (27%) | catalogued as rs1312967388; called by muse, mutect2, varscan2
- CTNNBL1 | c.1104C>T p.D368= | Silent (SNP) | VAF 95/299 reads (32%) | catalogued as COSV63747340; called by muse, mutect2, varscan2
- DNAAF3 | c.1293G>A p.R431= (on ENST00000524407 / NM_001256715.2; = p.R478= on NM_178837.4) | Silent (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- DNAH3 | c.2640C>T p.S880= | Silent (SNP) | VAF 79/325 reads (24%) | called by muse, mutect2, varscan2
- EMB | c.780C>T p.P260= | Silent (SNP) | VAF 83/243 reads (34%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1194C>A p.V398= | Silent (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
- FHOD3 | c.2130A>T p.V710= (on ENST00000359247 / NM_001281739.3; = p.V727= on NM_025135.5) | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- FSCB | c.2241T>A p.P747= | Silent (SNP) | VAF 56/203 reads (28%) | called by muse, varscan2
- GLMP | c.1185C>T p.H395= | Silent (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- GOLGA6B | c.603A>G p.L201= | Silent (SNP) | VAF 157/1800 reads (9%) | called by muse, mutect2
- H3C12 | c.7C>A p.R3= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV100377650; called by muse, mutect2, varscan2
- HIP1 | c.126C>T p.V42= | Silent (SNP) | VAF 61/276 reads (22%) | catalogued as rs1554502541; called by muse, mutect2, varscan2
- HRH1 | c.69C>A p.A23= | Silent (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- IFI16 | c.885C>T p.I295= | Silent (SNP) | VAF 69/196 reads (35%) | catalogued as rs149200088; called by muse, varscan2
- IGHV1-2 | c.72G>T p.V24= | Silent (SNP) | VAF 166/518 reads (32%) | catalogued as rs543047990; called by muse, mutect2, varscan2
- IL3RA | c.402C>G p.V134= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ITPR2 | c.4479T>C p.S1493= | Silent (SNP) | VAF 174/267 reads (65%) | called by mutect2, varscan2
- ITSN2 | c.2136A>G p.E712= | Silent (SNP) | VAF 62/141 reads (44%) | called by muse, mutect2, varscan2
- IZUMO4 | c.33G>C p.T11= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100642754, COSV100643115, COSV61433378; called by muse, mutect2, varscan2
- KCNJ10 | c.741C>A p.P247= | Silent (SNP) | VAF 105/430 reads (24%) | called by muse, mutect2, varscan2
- KIAA0408 | c.1530T>C p.D510= | Silent (SNP) | VAF 35/202 reads (17%) | called by muse, mutect2, varscan2
- KIAA1841 | c.567G>A p.E189= | Silent (SNP) | VAF 147/466 reads (32%) | catalogued as rs1438477156; called by muse, mutect2, varscan2
- KIF2B | c.478C>A p.R160= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as rs181862662; called by muse, mutect2, varscan2
- LCE2A | c.81G>A p.K27= | Silent (SNP) | VAF 85/237 reads (36%) | catalogued as rs368594795; called by muse, mutect2, varscan2
- MAGEC1 | c.654T>A p.P218= | Silent (SNP) | VAF 109/366 reads (30%) | called by muse, varscan2
- MDGA1 | c.1614G>T p.P538= | Silent (SNP) | VAF 60/157 reads (38%) | called by muse, mutect2, varscan2
- MDGA2 | c.1095C>T p.T365= (on ENST00000399232 / NM_001113498.2; = p.T67= on NM_182830.4) | Silent (SNP) | VAF 121/429 reads (28%) | called by muse, mutect2, varscan2
- MET | c.1875A>G p.T625= | Silent (SNP) | VAF 144/381 reads (38%) | called by muse, mutect2, varscan2
- MFN1 | c.1011C>T p.F337= | Silent (SNP) | VAF 90/423 reads (21%) | catalogued as rs543443619, COSV54938059; called by muse, mutect2, varscan2
- MLXIP | c.2412G>T p.T804= | Silent (SNP) | VAF 33/150 reads (22%) | called by muse, mutect2, varscan2
- MUC4 | c.15843C>A p.S5281= (on ENST00000463781 / NM_018406.7; = p.S1045= on NM_004532.6) | Silent (SNP) | VAF 40/754 reads (5%) | catalogued as COSV57793430; called by muse, mutect2
- NCOR1 | c.6432G>C p.S2144= | Silent (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- NTNG2 | c.588C>G p.T196= | Silent (SNP) | VAF 98/277 reads (35%) | called by muse, mutect2, varscan2
- OR4K13 | c.417G>A p.R139= | Silent (SNP) | VAF 57/166 reads (34%) | catalogued as COSV59859382; called by muse, mutect2, varscan2
- OR5W2 | c.351G>C p.V117= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV100747685, COSV60614915; called by muse, varscan2
- PCDHB5 | c.2121C>T p.F707= | Silent (SNP) | VAF 114/259 reads (44%) | catalogued as rs1554276252, COSV50650743; called by muse, mutect2, varscan2
- PGC | c.993A>T p.P331= | Silent (SNP) | VAF 48/148 reads (32%) | called by muse, mutect2, varscan2
- PINK1 | c.756G>A p.E252= | Silent (SNP) | VAF 140/299 reads (47%) | catalogued as rs1247061281; called by muse, mutect2, varscan2
- PLCB1 | c.1737C>T p.L579= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs761026739; called by muse, varscan2
- PLIN5 | c.198C>A p.G66= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs948489066; called by muse, mutect2, varscan2
- POTEI | c.861G>C p.V287= | Silent (SNP) | VAF 43/526 reads (8%) | catalogued as rs756127622; called by muse, mutect2
- PRUNE2 | c.4251A>G p.T1417= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs776863800; called by muse, mutect2, varscan2
- PTPRC | c.3268C>T p.L1090= | Silent (SNP) | VAF 116/395 reads (29%) | called by muse, mutect2, varscan2
- REPIN1 | c.18C>T p.C6= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs1391444255; called by muse, mutect2, varscan2
- RIN2 | c.1020G>A p.P340= (on ENST00000255006 / NM_001242581.1; = p.P291= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/184 reads (21%) | catalogued as rs776874726; called by muse, mutect2, varscan2
- RPA1 | c.96C>T p.P32= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as rs1242233838; called by muse, mutect2, varscan2
- RPRD2 | c.3240A>G p.E1080= | Silent (SNP) | VAF 45/200 reads (23%) | called by muse, mutect2, varscan2
- SEMA3A | c.1236A>T p.P412= | Silent (SNP) | VAF 84/412 reads (20%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.894C>T p.D298= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs774278546; called by muse, mutect2, varscan2
- SLC5A3 | c.1158C>T p.A386= | Silent (SNP) | VAF 78/214 reads (36%) | catalogued as rs761222681; called by muse, mutect2, varscan2
- SPEF2 | c.480A>G p.Q160= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- STAP1 | c.550C>A p.R184= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV55329407, COSV99609626; called by muse, mutect2, varscan2
- SYNE3 | c.738C>T p.C246= | Silent (SNP) | VAF 64/234 reads (27%) | catalogued as COSV62079826; called by muse, mutect2, varscan2
- TLR2 | c.630T>C p.H210= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs779455963; called by muse, mutect2, varscan2
- TMEM132C | c.48G>T p.G16= | Silent (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- TRIM58 | c.45G>T p.R15= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- TSBP1 | c.264T>C p.S88= (on ENST00000617061; = p.S112= on NM_006781.5) | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- USF3 | c.5397C>T p.S1799= | Silent (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
- A2ML1 | c.-5C>A | 5'UTR (SNP) | VAF 112/165 reads (68%) | called by muse, mutect2, varscan2
- AC073648.1 | n.689A>G | RNA (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- AC074085.2 | n.394G>T | RNA (SNP) | VAF 41/154 reads (27%) | called by muse, mutect2, varscan2
- AC091304.1 | n.573del | RNA (DEL) | VAF 10/78 reads (13%) | called by mutect2, varscan2
- AC112721.1 | n.252G>T | RNA (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- BTN2A3P | n.195G>T | RNA (SNP) | VAF 49/370 reads (13%) | catalogued as rs1257540384; called by muse, mutect2, varscan2
- C4orf50 | c.-955G>T | 5'UTR (SNP) | VAF 56/146 reads (38%) | called by muse, mutect2, varscan2
- COL21A1 | c.2408-40del | Intron (DEL) | VAF 65/224 reads (29%) | called by mutect2, pindel, varscan2
- CTSLP8 | n.671C>A | RNA (SNP) | VAF 72/248 reads (29%) | called by muse, mutect2, varscan2
- CYP4F24P | n.878T>C | RNA (SNP) | VAF 18/38 reads (47%) | catalogued as rs1259050229; called by muse, mutect2, varscan2
- DIP2C | c.85+38149C>A | Intron (SNP) | VAF 89/248 reads (36%) | called by muse, mutect2, varscan2
- DNAI2 | c.1211+1771G>C | Intron (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- FOLH1B | n.1339A>T | RNA (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- FYTTD1 | chr3:197749650 G>C | 5'Flank (SNP) | VAF 100/462 reads (22%) | called by muse, mutect2, varscan2
- GPM6A | c.37+24799A>G | Intron (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- H2AZ1 | c.81+81G>A | Intron (SNP) | VAF 446/1037 reads (43%) | called by muse, mutect2, varscan2
- HERC2P4 | n.192C>T | RNA (SNP) | VAF 96/344 reads (28%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2603G>C | Intron (SNP) | VAF 98/366 reads (27%) | called by muse, varscan2
- ITGAM | c.3390+40T>A | Intron (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2
- KCNK10 | c.37+3656G>C | Intron (SNP) | VAF 70/308 reads (23%) | catalogued as COSV100068096; called by muse, mutect2, varscan2
- KLHL26 | c.-24C>A | 5'UTR (SNP) | VAF 13/31 reads (42%) | catalogued as rs775388136; called by muse, varscan2
- MIR587 | n.37A>G | RNA (SNP) | VAF 69/187 reads (37%) | called by muse, mutect2, varscan2
- MME | c.*21G>T | 3'UTR (SNP) | VAF 53/484 reads (11%) | called by muse, mutect2, varscan2
- NDUFS7 | c.123-43C>A | Intron (SNP) | VAF 24/166 reads (14%) | catalogued as rs778337126, COSV99283069; called by muse, mutect2, varscan2
- NR5A2 | c.65-954G>C | Intron (SNP) | VAF 57/242 reads (24%) | catalogued as rs1257217575; called by muse, varscan2
- OBSCN | c.18662-2164C>T | Intron (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- PABPC1L | c.*60A>G | 3'UTR (SNP) | VAF 112/249 reads (45%) | catalogued as rs1338308419; called by muse, mutect2, varscan2
- POLR2H | c.-72G>T | 5'UTR (SNP) | VAF 81/670 reads (12%) | catalogued as COSV55600510; called by muse, mutect2, varscan2
- PRPF3 | c.1526+50dup | Intron (INS) | VAF 39/125 reads (31%) | called by mutect2, pindel, varscan2
- RABGEF1 | c.635-493C>T | Intron (SNP) | VAF 59/208 reads (28%) | catalogued as rs115494351; called by muse, mutect2, varscan2
- RMDN2 | c.452+20817G>A | Intron (SNP) | VAF 124/483 reads (26%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163123 G>T | 5'Flank (SNP) | VAF 24/281 reads (9%) | called by muse, mutect2, varscan2
- RN7SL484P | n.152G>T | RNA (SNP) | VAF 88/309 reads (28%) | called by muse, mutect2, varscan2
- RNF157 | c.-38G>A | 5'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- RPLP0 | c.55-523G>C | Intron (SNP) | VAF 88/227 reads (39%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23893A>G | Intron (SNP) | VAF 41/332 reads (12%) | called by muse, mutect2, varscan2
- SMOC1 | c.*35G>A | 3'UTR (SNP) | VAF 83/251 reads (33%) | called by muse, mutect2, varscan2
- SNORD114-1 | chr14:100949831 C>A | 5'Flank (SNP) | VAF 48/116 reads (41%) | called by muse, mutect2, varscan2
- SNORD114-23 | n.49C>T | RNA (SNP) | VAF 37/148 reads (25%) | catalogued as rs375612518; called by muse, mutect2, varscan2
- SPATA31C2 | n.1830T>C | RNA (SNP) | VAF 106/354 reads (30%) | called by muse, mutect2, varscan2
- SSPOP | n.868T>A | RNA (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- STK11IP | c.-56G>A | 5'UTR (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- TAFA5 | c.263-14348C>G | Intron (SNP) | VAF 159/253 reads (63%) | called by muse, mutect2, varscan2
- TLE4 | c.936+235G>C | Intron (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- TMIGD2 | c.*86T>A | 3'UTR (SNP) | VAF 24/147 reads (16%) | catalogued as COSV100010524; called by muse, mutect2, varscan2
- TSNAX-DISC1 | c.495+55624C>T | Intron (SNP) | VAF 63/231 reads (27%) | called by muse, mutect2, varscan2
- TTC19 | c.*1521C>T | 3'UTR (SNP) | VAF 15/66 reads (23%) | called by muse, varscan2
- USP6 | c.1079-191C>T | Intron (SNP) | VAF 33/75 reads (44%) | catalogued as rs767492166; called by muse, mutect2, varscan2
- ZNF733P | n.460C>T | RNA (SNP) | VAF 24/153 reads (16%) | catalogued as rs1196709679; called by muse, mutect2, varscan2
